Somatic mutation profile of tumor specimen TCGA-DK-A3IS-01A (aliquot TCGA-DK-A3IS-01A-21D-A21A-08) from TCGA case TCGA-DK-A3IS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 68.7 years (25,098 days).
Specimen TCGA-DK-A3IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fe517fc-c2f8-44e4-bf4c-0da624142e93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3IS-10A (Blood Derived Normal), aliquot TCGA-DK-A3IS-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4689806e-dd9d-4b4e-beb8-313aafa9cd06

The open-access MAF lists 388 somatic variants for this specimen: 269 protein-altering or splice-affecting, 109 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 232, Silent 109, Nonsense Mutation 25, Splice Site 7, Intron 4, 5'UTR 2, Translation Start Site 1, 3'UTR 1, Nonstop Mutation 1, 3'Flank 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- ABCC3 | c.2498G>A p.G833D | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53318297; called by muse, mutect2, varscan2
- ACOT11 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59346683; called by muse, mutect2, varscan2
- ACOX3 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379252320, COSV62711182; called by muse, mutect2
- ACP5 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54535500, COSV54537641; called by muse, mutect2, varscan2
- ACTR8 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1351632479, COSV51635451; called by muse, mutect2, varscan2
- ACVR2A | c.94T>G p.F32V | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV54019974; called by muse, mutect2, varscan2
- ADAMTS10 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV54352733; called by muse, mutect2, varscan2
- ADCY3 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747746171, COSV53165213; called by muse, varscan2
- AKAP9 | c.11613G>C p.Q3871H (on ENST00000359028; = p.Q3847H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as COSV50151045; called by muse, mutect2, varscan2
- AMOTL1 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 57/178 reads (32%) | catalogued as COSV54414894, COSV54417702; called by muse, mutect2, varscan2
- ANKRD34A | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV60160409, COSV60160521; called by muse, mutect2, varscan2
- ANKRD40 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV53332954; called by muse, mutect2, varscan2
- AP002748.5 | c.1770G>C p.E590D | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); catalogued as COSV59147384; called by muse, mutect2, varscan2
- APPL2 | c.1463C>A p.S488Y | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1279463973, COSV51588636; called by muse, mutect2, varscan2
- ARFGAP1 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 77/105 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV62262546; called by muse, mutect2, varscan2
- ARHGEF35 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65312466; called by muse, mutect2, varscan2
- ARHGEF7 | c.1483G>A p.E495K (on ENST00000375741 / NM_001113511.2; = p.E317K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs765860102, COSV54540099; called by muse, mutect2, varscan2
- ARVCF | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54265395; called by muse, mutect2, varscan2
- ATG3 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51926155; called by muse, mutect2, varscan2
- ATG4D | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 104/211 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs376428796; called by muse, mutect2, varscan2
- ATP2B1 | c.2767C>G p.L923V | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53805048; called by muse, mutect2, varscan2
- ATP6V0E1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 112/329 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV54183975; called by muse, mutect2, varscan2
- BGN | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 46/47 reads (98%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV104404279, COSV59036115; called by muse, mutect2
- BIRC3 | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV54815564; called by muse, mutect2, varscan2
- BMPR2 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM100454, COSV65807988; called by muse, mutect2, varscan2
- C1S | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs782484390, COSV61070311; called by muse, mutect2, varscan2
- C2orf15 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.214); catalogued as COSV56781581; called by muse, mutect2, varscan2
- C9 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV54675028; called by muse, mutect2, varscan2
- CAAP1 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 99/115 reads (86%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs576347270, COSV61700362; called by muse, mutect2, varscan2
- CAPRIN2 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV51831121; called by muse, mutect2, varscan2
- CCKBR | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV58099436, COSV58107007; called by muse, mutect2, varscan2
- CD101 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV56716713; called by muse, mutect2
- CDCA7L | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV62258420, COSV62261201; called by muse, mutect2, varscan2
- CELF5 | c.462C>G p.F154L | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV53010128; called by muse, mutect2, varscan2
- CEP162 | c.2491G>A p.D831N | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100003316, COSV57618180; called by muse, mutect2, varscan2
- CHERP | c.2193G>C p.K731N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); catalogued as COSV52222965; called by muse, mutect2, varscan2
- CHTF18 | c.2709G>C p.M903I | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV50210209; called by muse, mutect2, varscan2
- CLCN4 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 54/59 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs769848382, COSV66465499; called by muse, mutect2, varscan2
- COG1 | c.1829C>T p.S610L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV55428616; called by muse, mutect2, varscan2
- CORO6 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV61470298; called by muse, mutect2, varscan2
- CTCFL | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 207/338 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778383088, COSV54771685; called by muse, mutect2, varscan2
- CYP1B1 | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs916479886, CD076779, COSV52223002; called by muse, mutect2, varscan2
- CYP27C1 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.088); catalogued as COSV58866378; called by muse, varscan2
- CYP4F12 | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.694); catalogued as COSV61172776, COSV61174877; called by muse, mutect2, varscan2
- DBF4 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1237261569; called by muse, mutect2, varscan2
- DENND4A | c.3925G>C p.D1309H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71265401; called by muse, mutect2, varscan2
- DENND5B | c.3797G>A p.G1266E | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.281); catalogued as COSV60900671; called by muse, varscan2
- DIP2B | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56580268; called by muse, mutect2, varscan2
- DNAH3 | c.7888G>C p.E2630Q | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.772); catalogued as COSV54509054; called by muse, mutect2, varscan2
- DNMT1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61577201; called by muse, mutect2, varscan2
- DOCK9 | c.2081G>C p.R694T (on ENST00000376460 / NM_001366676.2; = p.R695T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59622786, COSV59641056; called by muse, mutect2, varscan2
- DYNC2H1 | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV62088903; called by muse, mutect2, varscan2
- ECM2 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60739434; called by muse, mutect2, varscan2
- EFCC1 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs992938176, COSV71401743; called by muse, mutect2, varscan2
- EIF3L | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs992209191, COSV66045567; called by muse, mutect2, varscan2
- ERICH3 | c.3731C>A p.A1244E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV58601622; called by muse, mutect2, varscan2
- EVA1B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54633673; called by muse, mutect2, varscan2
- EXPH5 | c.2330A>T p.D777V | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56199677; called by muse, mutect2, varscan2
- FAM117A | c.550C>G p.H184D | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV53631030, COSV53633255; called by muse, mutect2, varscan2
- FAM13A | c.1931C>G p.S644C | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51998667; called by muse, mutect2, varscan2
- FAM83B | c.376C>A p.H126N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV60922608; called by muse, mutect2, varscan2
- FAT2 | c.3584C>G p.S1195C | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55815234; called by muse, mutect2, varscan2
- FBXO30 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52790470; called by muse, mutect2, varscan2
- FNBP4 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV55446986, COSV55449457; called by muse, mutect2, varscan2
- FNIP1 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV57194630; called by muse, mutect2, varscan2
- FRYL | c.8482G>C p.E2828Q | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1425666177, COSV51940102, COSV51942003; called by muse, mutect2, varscan2
- GAL3ST1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs757152961, COSV58892084; called by mutect2, varscan2
- GDF11 | c.366C>G p.D122E | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV57689380; called by muse, mutect2, varscan2
- GDPD1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52380960; called by muse, mutect2, varscan2
- GK2 | c.410T>A p.V137D | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV62626266; called by muse, mutect2, varscan2
- GRM5 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59595328, COSV59608546; called by muse, mutect2, varscan2
- GTSF1L | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 84/131 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV65932447; called by muse, mutect2, varscan2
- H3C4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV61911648, COSV61911890; called by muse, mutect2, varscan2
- HDLBP | c.1615G>C p.E539Q | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as COSV60492871; called by muse, mutect2, varscan2
- HECW2 | c.3329C>T p.S1110L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV53652301; called by mutect2, varscan2
- HERC1 | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757806758, COSV71246594; called by muse, mutect2, varscan2
- HFM1 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV54031945, COSV99645833; called by muse, mutect2
- HIVEP3 | c.5084C>T p.S1695F | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs1333001849, COSV56011019; called by muse, mutect2, varscan2
- HRC | c.1399G>C p.G467R | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.444); catalogued as COSV53255529; called by muse, mutect2, varscan2
- HRH1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs201217782, COSV67955148; called by muse, mutect2, varscan2
- HTATSF1 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV54477753; called by muse, mutect2, varscan2
- HTT | c.9377A>G p.Y3126C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61858632; called by muse, mutect2, varscan2
- IGLV8-61 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV66502583; called by muse, mutect2, varscan2
- IGSF3 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs1324614877; called by muse, mutect2, varscan2
- IKZF2 | c.516C>A p.F172L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV59577077; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1058-1G>C p.X353_splice | Splice Site (SNP) | VAF 119/127 reads (94%) | catalogued as COSV56244151; called by muse, mutect2, varscan2
- IMPG1 | c.553A>T p.I185F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64055196; called by muse, mutect2, varscan2
- ITGA11 | c.620G>C p.G207A | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV59875659; called by muse, mutect2, varscan2
- ITGA3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.215); catalogued as COSV50306606; called by muse, mutect2, varscan2
- ITGA6 | c.2516C>T p.S839L (on ENST00000442250; = p.S800L on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs755358939, COSV51220406; called by muse, mutect2, varscan2
- ITGB4 | c.4125C>G p.F1375L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV52322732; called by muse, mutect2, varscan2
- ITIH6 | c.2918C>T p.S973F | Missense Mutation (SNP) | VAF 27/27 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV54487272; called by muse, mutect2, varscan2
- KCNJ10 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 171/209 reads (82%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV63633066; called by muse, mutect2, varscan2
- KCNJ12 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1555562535, COSV59164401; called by muse, varscan2
- KDM6A | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 62/65 reads (95%) | catalogued as COSV100937869, COSV100938273; called by muse, mutect2, varscan2
- KIAA1109 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs764925090, COSV52665184; called by muse, mutect2, varscan2
- KIF15 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV58159039; called by muse, mutect2, varscan2
- KLHL6 | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58064990; called by muse, mutect2, varscan2
- KLK8 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV51591074; called by muse, mutect2, varscan2
- KMT2B | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV52889779; called by muse, varscan2
- KMT2C | c.5140G>C p.D1714H | Missense Mutation (SNP) | VAF 217/495 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375389693; called by muse, mutect2, varscan2
- KMT2C | c.4541-1G>C p.X1514_splice | Splice Site (SNP) | VAF 33/70 reads (47%) | catalogued as COSV100070545, COSV51405075; called by muse, mutect2, varscan2
- KRT20 | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs886571542, COSV51424121; called by muse, mutect2, varscan2
- KRT6C | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52876785; called by muse, mutect2, varscan2
- LAPTM4A | c.170T>A p.M57K | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV51532075, COSV51533182; called by muse, mutect2
- LMTK2 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as COSV51992119, COSV99806838; called by muse, mutect2, varscan2
- LNX1 | c.1892+2del p.X631_splice (on ENST00000263925 / NM_001126328.3; = p.X535_splice on NM_032622.2) | Splice Site (DEL) | VAF 31/173 reads (18%) | catalogued as COSV55783066; called by mutect2, pindel, varscan2
- LRP1B | c.10987G>A p.D3663N | Missense Mutation (SNP) | VAF 147/277 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67196519; called by muse, mutect2, varscan2
- MAGI2 | c.3970G>A p.A1324T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as rs757602487; called by muse, mutect2, varscan2
- MAST3 | c.2854G>T p.V952F | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV53218248; called by muse, mutect2, varscan2
- MECOM | c.1969G>C p.E657Q (on ENST00000468789 / NM_001105078.4; = p.E845Q on NM_004991.4) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV52961040; called by muse, mutect2, varscan2
- MEPCE | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV52768817; called by muse, mutect2, varscan2
- MKKS | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751549537, COSV61398127; called by muse, mutect2, varscan2
- MOCS3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 77/301 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54865821; called by muse, mutect2, varscan2
- MOGAT3 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV56173109; called by muse, mutect2, varscan2
- MRPS22 | c.42G>C p.L14F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.127); catalogued as COSV60349324; called by muse, mutect2, varscan2
- MSH3 | c.1920G>C p.L640F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV54146539, COSV54160580; called by muse, mutect2, varscan2
- MTMR14 | c.1900G>C p.E634Q (on ENST00000296003 / NM_001077525.3; = p.E522Q on NM_022485.5) | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as rs751079388, COSV56003811; called by muse, mutect2, varscan2
- MUC16 | c.9287C>A p.S3096* | Nonsense Mutation (SNP) | VAF 103/194 reads (53%) | catalogued as COSV67457919; called by muse, mutect2, varscan2
- MUC16 | c.9005C>T p.S3002L | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV67452235; called by muse, mutect2, varscan2
- MX2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.457); catalogued as COSV58095541; called by muse, mutect2, varscan2
- MYO3B | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.393); catalogued as COSV58697285; called by muse, mutect2, varscan2
- N4BP2 | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV54699984; called by muse, mutect2, varscan2
- NASP | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.971); catalogued as COSV59646116; called by muse, mutect2, varscan2
- NBR1 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs776865499, COSV57831223; called by muse, mutect2, varscan2
- NCSTN | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477792516, COSV54186032, COSV54190873; called by muse, mutect2, varscan2
- NECTIN2 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52976255; called by muse, varscan2
- NELFA | c.1303C>T p.Q435* (on ENST00000542778; = p.Q424* on NM_005663.5) | Nonsense Mutation (SNP) | VAF 65/111 reads (59%) | catalogued as rs1420161239; called by muse, mutect2, varscan2
- NGLY1 | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 53/112 reads (47%) | catalogued as rs754379411; called by muse, mutect2, varscan2
- NHEJ1 | c.338C>G p.S113C | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55405890; called by muse, mutect2, varscan2
- NLRP2 | c.1056C>G p.I352M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV54753072; called by muse, mutect2, varscan2
- NOC3L | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64929687; called by muse, mutect2, varscan2
- NOMO1 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.073); catalogued as COSV55057467, COSV55058842; called by muse, mutect2, varscan2
- NOS3 | c.501G>C p.E167D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.365); catalogued as COSV52487172; called by muse, mutect2, varscan2
- OBP2B | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV64402307; called by muse, mutect2, varscan2
- OGDH | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 109/247 reads (44%) | catalogued as COSV56048712, COSV56053761, COSV99758179; called by muse, mutect2, varscan2
- OIP5 | c.29C>G p.S10* | Nonsense Mutation (SNP) | VAF 73/150 reads (49%) | catalogued as rs201962885; called by muse, mutect2, varscan2
- OR3A2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV68694974; called by muse, mutect2, varscan2
- OR4C15 | c.453G>A p.M151I (on ENST00000314644; = p.M97I on NM_001001920.2) | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as rs763726329, COSV58951556; called by muse, mutect2, varscan2
- OR5L2 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 176/248 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs376554037, COSV65724286; called by muse, mutect2, varscan2
- OTOP1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs547101628, COSV56391427; called by muse, mutect2, varscan2
- OTULIN | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52505151; called by muse, mutect2, varscan2
- PAPOLA | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV53479705; called by muse, mutect2, varscan2
- PCNT | c.8761G>A p.E2921K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV64026030; called by muse, mutect2, varscan2
- PCNX2 | c.5146G>A p.E1716K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as rs369348878, COSV50847760; called by muse, mutect2, varscan2
- PDGFRB | c.2904+1G>T p.X968_splice | Splice Site (SNP) | VAF 61/102 reads (60%) | catalogued as COSV55802187; called by muse, mutect2, varscan2
- PDIA3 | c.635C>G p.T212S | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV55855056; called by muse, mutect2, varscan2
- PEX26 | c.230+1G>C p.X77_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | catalogued as CS060557, COSV61604192; called by muse, mutect2, varscan2
- PHKA1 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV59803083; called by muse, mutect2, varscan2
- PLCG2 | c.3336C>G p.I1112M | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV63867910; called by muse, mutect2, varscan2
- PLEKHA3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV52293380; called by muse, mutect2, varscan2
- POLN | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as COSV67023883; called by muse, varscan2
- PPL | c.2474G>A p.R825K | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV62045260; called by muse, mutect2, varscan2
- PRDX2 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56877483; called by muse, mutect2, varscan2
- PREX1 | c.3572C>G p.S1191C | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64248891; called by muse, mutect2, varscan2
- PRICKLE2 | c.1395G>C p.Q465H (on ENST00000295902; = p.Q409H on NM_198859.4) | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.694); catalogued as COSV55763921; called by muse, mutect2, varscan2
- PRIMPOL | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775404693, COSV59248099; called by muse, mutect2, varscan2
- PSIP1 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 37/43 reads (86%) | catalogued as COSV66253781; called by muse, mutect2, varscan2
- PTAFR | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV59536224; called by muse, mutect2, varscan2
- PTPN4 | c.1958G>C p.G653A | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55298663; called by muse, mutect2, varscan2
- QRFPR | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs146756169, COSV57675649; called by muse, mutect2, varscan2
- RFPL4B | c.735C>G p.F245L | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV71437160; called by muse, mutect2, varscan2
- RHOBTB3 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.658); catalogued as COSV66101330, COSV66102758; called by muse, varscan2
- RHOBTB3 | c.117G>C p.E39D | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV66101333; called by muse, varscan2
- RNF213 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.4); catalogued as rs142962817; called by muse, mutect2, varscan2
- RNPEPL1 | c.1671C>G p.I557M | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); catalogued as COSV54372100; called by muse, mutect2, varscan2
- RRP1B | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61478573; called by muse, mutect2, varscan2
- RSPH10B | c.2333A>G p.K778R | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV58073494; called by muse, mutect2, varscan2
- RTF1 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1489958895, COSV67477820; called by muse, mutect2, varscan2
- RUVBL1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV59475213; called by muse, mutect2, varscan2
- RXFP2 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53633843; called by muse, mutect2, varscan2
- SEMA3F | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs780205478, COSV50028582; called by muse, mutect2, varscan2
- SEMA5B | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52089825, COSV99531138; called by muse, mutect2, varscan2
- SENP7 | c.2111C>G p.S704* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV58608587, COSV58617637; called by muse, varscan2
- SERPIND1 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs765822510, COSV53137708; called by muse, mutect2, varscan2
- SIN3A | c.3397A>G p.I1133V | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as rs749092824, COSV64582127; called by muse, mutect2, varscan2
- SLC15A3 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV57171078; called by muse, mutect2, varscan2
- SLC17A6 | c.1117C>G p.L373V | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV54134278, COSV54135092; called by muse, mutect2, varscan2
- SLC27A2 | c.1338G>C p.E446D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV51057932; called by muse, mutect2, varscan2
- SLC49A4 | c.736A>T p.T246S | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV53745879; called by muse, mutect2, varscan2
- SLC4A4 | c.656C>A p.S219Y (on ENST00000264485 / NM_001098484.3; = p.S175Y on NM_003759.4) | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV52617568; called by muse, mutect2, varscan2
- SLK | c.2125C>G p.L709V | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1410467015, COSV59824335; called by muse, mutect2, varscan2
- SMC5 | c.263G>C p.S88T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV63191992; called by muse, mutect2, varscan2
- SNCAIP | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV54404415, COSV99748128; called by muse, mutect2, varscan2
- SNED1 | c.2120C>A p.A707D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV60020512; called by muse, mutect2, varscan2
- SPEN | c.8713G>A p.D2905N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1456771008, COSV65358945; called by muse, mutect2, varscan2
- SPTBN1 | c.5834C>G p.S1945C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV61686404; called by muse, mutect2, varscan2
- SPTLC2 | c.1490G>C p.G497A | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV53638827; called by muse, mutect2, varscan2
- SPTSSB | c.9G>C p.L3F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV63219032; called by muse, mutect2, varscan2
- SREBF2 | c.2143G>C p.E715Q | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as COSV63330583, COSV63330645; called by muse, mutect2, varscan2
- SRP72 | c.1463T>A p.I488N | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61377130; called by muse, mutect2, varscan2
- ST14 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53831961; called by muse, mutect2, varscan2
- ST3GAL5 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV60385177, COSV60386981; called by muse, mutect2, varscan2
- STAG2 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 25/28 reads (89%) | catalogued as COSV54356717, COSV54365939, COSV54376336; called by muse, mutect2, varscan2
- STAU1 | c.1011G>C p.K337N (on ENST00000371856 / NM_001319135.1; = p.K256N on NM_004602.3) | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61459348; called by muse, mutect2, varscan2
- SYMPK | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55610169; called by muse, mutect2, varscan2
- SYNJ2 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778353772, COSV62895971; called by muse, mutect2, varscan2
- TACC3 | c.1662G>T p.L554F | Missense Mutation (SNP) | VAF 882/1377 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV57603335, COSV57604198; called by muse, varscan2
- TAF4 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 161/253 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53335396; called by muse, mutect2, varscan2
- TBC1D14 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV68984860; called by muse, mutect2
- TBC1D4 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs587777260, CM093437, COSV104427297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX26 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as COSV66839568; called by muse, mutect2, varscan2
- THAP12 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as COSV52609789; called by muse, mutect2, varscan2
- THAP12 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV99473244; called by muse, mutect2, varscan2
- TMBIM4 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.315); catalogued as COSV53968159; called by muse, mutect2, varscan2
- TMC2 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV62650556, COSV62659206; called by muse, mutect2, varscan2
- TMEM50A | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65486186; called by muse, mutect2, varscan2
- TMEM63C | c.1266C>G p.F422L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV53601905; called by muse, mutect2, varscan2
- TNS3 | c.474-1G>A p.X158_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | catalogued as COSV60788128; called by muse, mutect2, varscan2
- TPSAB1 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58780087; called by muse, varscan2
- TRPC4 | c.1951G>T p.G651C | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58993371; called by muse, mutect2, varscan2
- TRPS1 | c.1391C>T p.S464L (on ENST00000220888 / NM_001330599.2; = p.S477L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs753537419, COSV55243024; called by muse, mutect2, varscan2
- U2AF1L4 | c.616G>C p.E206Q (on ENST00000412391; = p.E147D on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.103); catalogued as COSV53073954; called by muse, mutect2, varscan2
- URGCP | c.2268G>C p.L756F (on ENST00000453200 / NM_001077663.3; = p.L747F on NM_017920.4) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV56245669; called by muse, mutect2, varscan2
- USHBP1 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV53102574; called by muse, mutect2, varscan2
- USP10 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs757533007, COSV54747569; called by muse, mutect2, varscan2
- UTP14C | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73000596; called by muse, mutect2, varscan2
- VWA3B | c.1648G>C p.D550H | Missense Mutation (SNP) | VAF 90/157 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68241515; called by muse, mutect2, varscan2
- VWA7 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65172650; called by muse, mutect2, varscan2
- WDR13 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV54331006; called by muse, mutect2, varscan2
- WDR44 | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54161183; called by muse, mutect2, varscan2
- WSB2 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59573399; called by muse, mutect2, varscan2
- ZAN | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.636); catalogued as rs755981747, COSV61806379; called by muse, mutect2, varscan2
- ZAN | c.6736G>A p.E2246K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61806389; called by muse, mutect2, varscan2
- ZBTB38 | c.1208G>C p.G403A | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV58540603; called by muse, mutect2, varscan2
- ZBTB41 | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 73/103 reads (71%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.201); catalogued as COSV66358825; called by muse, mutect2, varscan2
- ZC3HC1 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 147/412 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61297560; called by muse, mutect2, varscan2
- ZDHHC6 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as rs756920148, COSV61129393; called by muse, varscan2
- ZFHX4 | c.2385G>A p.M795I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV50594964; called by muse, mutect2, varscan2
- ZFHX4 | c.4462G>C p.E1488Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.295); catalogued as rs781595773, COSV50596032, COSV50632736; called by muse, mutect2, varscan2
- ZFR | c.2906G>C p.R969T | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54051135; called by muse, mutect2, varscan2
- ZMIZ1 | c.3172G>A p.D1058N | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as COSV57891336; called by muse, mutect2, varscan2
- ZMYM2 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.971); catalogued as COSV67032816, COSV67035858; called by muse, mutect2, varscan2
- ZNF224 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV61241791; called by muse, mutect2, varscan2
- ZNF559 | c.1452G>T p.M484I | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV57835158; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV58672781; called by muse, mutect2, varscan2
- ZNF600 | c.1726C>T p.H576Y | Missense Mutation (SNP) | VAF 131/270 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57741752; called by muse, mutect2, varscan2
- ZNF846 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.187); catalogued as COSV67411871; called by muse, mutect2, varscan2
- ZNF846 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.02); catalogued as COSV67411874; called by muse, mutect2, varscan2
- ARHGEF2 | c.2041C>T p.R681* (on ENST00000361247 / NM_001162383.2; = p.R653* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- ASAP1 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- CAD | c.6451C>T p.R2151* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- DAZAP1 | c.1089_1091delinsTT p.S364* | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | called by pindel, varscan2*
- EMC1 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.039); called by muse, mutect2
- FAM13A | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- FNDC7 | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- GGNBP2 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- HES4 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- HINFP | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- INTS2 | c.1329C>T p.V443= | Splice Region (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2
- KIAA1109 | c.2538G>C p.M846I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- LRRC45 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.265); called by muse, varscan2
- MUC16 | c.8759C>T p.S2920L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- MYO1H | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- NCOA2 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 56/153 reads (37%) | called by muse, mutect2, varscan2
- NEB | c.15583C>G p.L5195V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PBLD | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- SGTB | c.788C>G p.S263* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TAAR5 | c.1013G>C p.*338Sext*? | Nonstop Mutation (SNP) | VAF 40/74 reads (54%) | called by muse, mutect2, varscan2
- TEX11 | c.187G>T p.E63* (on ENST00000344304; = p.E48* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- TFAM | c.441+2T>G p.X147_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- TMEM156 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.77); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TP53 | c.718dup p.S240Kfs*24 | Frame Shift Ins (INS) | VAF 57/96 reads (59%) | called by mutect2, pindel, varscan2
- YTHDF3 | c.1480C>G p.Q494E | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, varscan2
- ZMYM4 | c.1574C>G p.S525* | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- ZNF622 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- ZNF846 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 47/146 reads (32%) | called by muse, mutect2, varscan2
- ABCA5 | c.3672C>G p.L1224= | Silent (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- ACAN | c.2742G>A p.V914= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs780636375, COSV61357479; called by muse, mutect2, varscan2
- ADAMTS12 | c.573G>A p.P191= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs143045075; called by muse, mutect2, varscan2
- ARHGEF37 | c.909C>T p.F303= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as rs747173296, COSV61368150; called by muse, mutect2, varscan2
- ARHGEF38 | c.330C>G p.L110= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV54441360, COSV54441904; called by muse, mutect2, varscan2
- BBOX1 | c.180G>A p.V60= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1426160985, COSV54189761, COSV99589435, COSV99589467; called by muse, mutect2, varscan2
- BGN | c.63G>A p.Q21= | Silent (SNP) | VAF 40/41 reads (98%) | catalogued as COSV59036099; called by muse, mutect2
- BTNL2 | c.1296C>T p.D432= | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as rs771592654, COSV66630149; called by muse, mutect2
- C10orf71 | c.1521G>A p.R507= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1467154404, COSV60505579; called by muse, mutect2, varscan2
- C12orf60 | c.57C>T p.F19= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV57451286, COSV57451835; called by muse, mutect2, varscan2
- CEP131 | c.1695G>T p.L565= (on ENST00000269392 / NM_001319228.2; = p.L562= on NM_014984.4) | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV53951232; called by muse, mutect2, varscan2
- CHD3 | c.1026C>T p.V342= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV57873191; called by muse, mutect2, varscan2
- COL6A1 | c.1764G>A p.P588= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs542688326, COSV62611990; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP4F12 | c.1191C>T p.F397= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as COSV61172764; called by muse, mutect2, varscan2
- DDR2 | c.2055C>G p.T685= | Silent (SNP) | VAF 255/321 reads (79%) | catalogued as COSV63369844; called by muse, mutect2, varscan2
- DELE1 | c.1119G>A p.V373= | Silent (SNP) | VAF 75/113 reads (66%) | catalogued as COSV52003997; called by muse, mutect2, varscan2
- DGKA | c.1617C>T p.I539= | Silent (SNP) | VAF 88/151 reads (58%) | catalogued as COSV59384869; called by muse, mutect2, varscan2
- DHX37 | c.1554G>A p.K518= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as COSV58132722; called by muse, varscan2
- DNAH10 | c.12663C>G p.L4221= (on ENST00000409039; = p.L4160= on NM_207437.3) | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV68989580; called by muse, mutect2, varscan2
- DYNC1LI2 | c.840C>G p.L280= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV50754219; called by muse, mutect2, varscan2
- ENTPD4 | c.1782G>A p.R594= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs1281274169, COSV62268473; called by muse, mutect2, varscan2
- ERBB2 | c.2115G>A p.A705= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1326179459, COSV54065457; called by muse, mutect2, varscan2
- ETV4 | c.1104G>A p.E368= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV52251550; called by muse, mutect2, varscan2
- FBXO21 | c.1521C>T p.L507= (on ENST00000330622 / NM_033624.3; = p.L500= on NM_015002.3) | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as COSV57971979; called by muse, mutect2, varscan2
- FGGY | c.1452C>G p.S484= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV58026973, COSV58046049; called by muse, mutect2, varscan2
- FOXF1 | c.213G>A p.L71= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as COSV52285330; called by muse, mutect2, varscan2
- FOXK2 | c.246C>T p.I82= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as rs1427001484, COSV58877103, COSV58877611; called by muse, mutect2, varscan2
- GABRE | c.1494C>G p.L498= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as COSV64819137; called by muse, mutect2, varscan2
- GALK1 | c.552C>T p.I184= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV56689785, COSV56692431; called by muse, mutect2, varscan2
- GDAP1 | c.459G>T p.P153= | Silent (SNP) | VAF 50/125 reads (40%) | catalogued as COSV55185044; called by muse, mutect2, varscan2
- GIT1 | c.1287G>A p.L429= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV56401941; called by muse, mutect2, varscan2
- GLT8D2 | c.657C>T p.I219= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV62561317; called by muse, mutect2, varscan2
- GPN1 | c.474G>A p.S158= | Silent (SNP) | VAF 83/138 reads (60%) | catalogued as rs910063077, COSV53113171; called by muse, mutect2, varscan2
- GSAP | c.510G>A p.L170= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV57528745; called by muse, mutect2, varscan2
- HCAR1 | c.405C>T p.I135= | Silent (SNP) | VAF 80/158 reads (51%) | catalogued as COSV63672198; called by muse, mutect2, varscan2
- HSPA8 | c.150G>A p.L50= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV57082963; called by muse, mutect2, varscan2
- IL31RA | c.582C>T p.F194= | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as rs370085931, COSV51679976; called by muse, mutect2, varscan2
- INTS12 | c.1347G>A p.Q449= | Silent (SNP) | VAF 80/216 reads (37%) | catalogued as COSV100415692, COSV60861805; called by muse, mutect2, varscan2
- IQGAP1 | c.3513G>A p.L1171= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as COSV51582500; called by muse, mutect2, varscan2
- ITGAX | c.2145C>T p.F715= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV51642718; called by muse, mutect2, varscan2
- KCNC1 | c.204G>A p.L68= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs1174794886, COSV56392340; called by muse, mutect2, varscan2
- KIRREL3 | c.2148C>A p.L716= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV69383799, COSV69384345; called by muse, mutect2, varscan2
- KRT79 | c.459C>T p.F153= | Silent (SNP) | VAF 94/246 reads (38%) | catalogued as rs376301539, COSV57941207; called by muse, varscan2
- KRT79 | c.381C>G p.L127= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as COSV57938826; called by muse, varscan2
- KRTAP10-7 | c.39G>A p.L13= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as COSV59109614; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.633G>A p.S211= | Silent (SNP) | VAF 61/125 reads (49%) | catalogued as rs769768261, COSV53276321; called by muse, mutect2, varscan2
- LYZL6 | c.446G>A p.*149= | Silent (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
- MAGEA10 | c.645G>A p.L215= | Silent (SNP) | VAF 55/64 reads (86%) | catalogued as COSV54883269; called by muse, mutect2, varscan2
- MED1 | c.3930G>A p.L1310= | Silent (SNP) | VAF 49/122 reads (40%) | catalogued as COSV56123040; called by muse, mutect2, varscan2
- MPHOSPH6 | c.9C>T p.A3= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs568887770, COSV50736582; called by mutect2, varscan2
- NANS | c.936C>T p.L312= | Silent (SNP) | VAF 36/40 reads (90%) | catalogued as rs1277069312, COSV52963228; called by muse, mutect2, varscan2
- NECTIN2 | c.702C>T p.V234= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV52976235, COSV52980768; called by muse, varscan2
- NFIL3 | c.729C>T p.I243= | Silent (SNP) | VAF 53/63 reads (84%) | catalogued as COSV52683201; called by muse, mutect2, varscan2
- NKAPD1 | c.33G>T p.L11= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV54775001; called by muse, mutect2, varscan2
- NLRP12 | c.1146G>A p.E382= | Silent (SNP) | VAF 132/354 reads (37%) | catalogued as COSV60744534; called by muse, mutect2, varscan2
- NMRK2 | c.178C>T p.L60= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV51455050; called by muse, mutect2, varscan2
- NPR2 | c.1935C>G p.L645= | Silent (SNP) | VAF 88/99 reads (89%) | catalogued as COSV61040032, COSV61042005; called by muse, mutect2, varscan2
- NSFL1C | c.732G>T p.V244= | Silent (SNP) | VAF 94/192 reads (49%) | catalogued as COSV53792154; called by muse, mutect2, varscan2
- NTM | c.807G>A p.V269= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1052889889; called by muse, mutect2
- OR10G8 | c.198C>T p.F66= | Silent (SNP) | VAF 55/173 reads (32%) | catalogued as COSV70908238; called by muse, mutect2, varscan2
- PACSIN1 | c.1212C>G p.L404= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as COSV55059030, COSV99763127; called by muse, mutect2, varscan2
- PAK5 | c.2085C>T p.L695= | Silent (SNP) | VAF 105/262 reads (40%) | catalogued as rs141553527; called by muse, mutect2, varscan2
- PAN2 | c.2052C>G p.L684= | Silent (SNP) | VAF 125/224 reads (56%) | catalogued as COSV57753077, COSV57753082; called by muse, mutect2, varscan2
- PCDHA8 | c.1452G>A p.A484= | Silent (SNP) | VAF 60/161 reads (37%) | catalogued as COSV100969429, COSV65324193; called by muse, mutect2, varscan2
- PIP4K2B | c.48C>G p.L16= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs759101679; called by muse, mutect2, varscan2
- PLEKHA5 | c.1137C>G p.V379= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV54695974; called by muse, mutect2, varscan2
- PPP1R13L | c.667C>T p.L223= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs753059937; called by muse, mutect2, varscan2
- PROCA1 | c.15G>A p.T5= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV56385547; called by muse, mutect2, varscan2
- PSAPL1 | c.600C>A p.S200= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV59842568; called by muse, mutect2, varscan2
- PTAFR | c.51C>G p.L17= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as COSV59536239, COSV59537774; called by muse, mutect2, varscan2
- PTPN9 | c.783C>T p.F261= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV60722906; called by muse, mutect2, varscan2
- RAET1E | c.729C>T p.L243= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as COSV61722225; called by muse, mutect2, varscan2
- RAET1E | c.552C>G p.L184= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV61722236; called by muse, mutect2, varscan2
- RELCH | c.3300G>A p.Q1100= | Silent (SNP) | VAF 44/73 reads (60%) | catalogued as COSV56883164; called by muse, mutect2, varscan2
- RNF11 | c.367C>T p.L123= | Silent (SNP) | VAF 33/229 reads (14%) | catalogued as COSV54376086; called by muse, mutect2, varscan2
- SACS | c.8685C>T p.N2895= | Silent (SNP) | VAF 39/68 reads (57%) | catalogued as COSV66536132, COSV66545718; called by muse, mutect2, varscan2
- SACS | c.2262C>T p.F754= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV66536139; called by muse, mutect2, varscan2
- SEPTIN5 | c.831T>C p.H277= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs558411158, COSV63530443; called by muse, mutect2, varscan2
- SERPINA11 | c.216C>T p.N72= | Silent (SNP) | VAF 96/221 reads (43%) | catalogued as rs1470043656, COSV58241352; called by muse, mutect2, varscan2
- SLC35C2 | c.390C>A p.I130= | Silent (SNP) | VAF 51/210 reads (24%) | catalogued as rs1263839501, COSV54756270; called by muse, mutect2, varscan2
- SMARCA4 | c.2427C>T p.I809= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs773895427, COSV60789323; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNAPC2 | c.207C>G p.L69= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV55603099; called by muse, mutect2, varscan2
- SPIB | c.366G>A p.P122= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs778109814, COSV54529860; called by muse, mutect2, varscan2
- SPTAN1 | c.1314G>A p.V438= | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as rs751295099, COSV63985836; called by muse, mutect2, varscan2
- SPTBN1 | c.5748C>T p.F1916= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as COSV61686396; called by muse, varscan2
- ST8SIA5 | c.738G>A p.L246= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV59330450; called by muse, mutect2, varscan2
- SYNGR3 | c.603C>T p.G201= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV50192133; called by muse, mutect2, varscan2
- TAP1 | c.408C>T p.L136= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV62753978; called by muse, mutect2, varscan2
- TBC1D14 | c.201G>A p.G67= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV68984847; called by muse, mutect2
- TDP1 | c.750C>T p.L250= | Silent (SNP) | VAF 53/86 reads (62%) | catalogued as COSV59642464; called by muse, mutect2, varscan2
- TENM1 | c.123C>T p.N41= | Silent (SNP) | VAF 71/165 reads (43%) | catalogued as COSV64427106; called by muse, mutect2, varscan2
- TENM4 | c.2019C>T p.C673= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs373351012; called by muse, mutect2, varscan2
- TMEM231 | c.552G>A p.L184= (on ENST00000258173 / NM_001077418.3; = p.L213= on NM_001077416.2) | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as COSV50737922; called by muse, mutect2, varscan2
- TMOD2 | c.834G>A p.L278= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV51043009; called by muse, mutect2, varscan2
- TOP1MT | c.288T>C p.Y96= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as COSV61316724; called by muse, mutect2, varscan2
- TRIP12 | c.3444C>T p.V1148= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV52260525; called by muse, mutect2, varscan2
- TRMT6 | c.204G>A p.V68= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV52542915; called by muse, mutect2, varscan2
- TRPM5 | c.1233G>A p.T411= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs199917878; called by muse, mutect2, varscan2
- TTC29 | c.970C>T p.L324= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV57272745; called by muse, mutect2, varscan2
- UBR5 | c.4644C>A p.I1548= | Silent (SNP) | VAF 20/235 reads (9%) | catalogued as COSV55282156; called by muse, mutect2
- WDR20 | c.195C>G p.L65= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV54470982, COSV54472611, COSV54475638; called by muse, mutect2, varscan2
- WIPI1 | c.648C>T p.V216= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV50929631; called by muse, mutect2, varscan2
- YTHDF3 | c.1395C>T p.F465= | Silent (SNP) | VAF 25/55 reads (45%) | called by muse, varscan2
- ZBTB7C | c.1221G>A p.L407= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV59687960; called by muse, mutect2, varscan2
- ZC3H4 | c.321G>A p.R107= | Silent (SNP) | VAF 153/411 reads (37%) | catalogued as COSV53411118; called by muse, mutect2, varscan2
- ZFP64 | c.906C>G p.L302= | Silent (SNP) | VAF 51/235 reads (22%) | catalogued as COSV53797185; called by muse, mutect2, varscan2
- ZNF320 | c.1014C>T p.F338= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as COSV67087713; called by muse, mutect2, varscan2
- ZNF43 | c.2109G>A p.E703= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV61683214; called by muse, mutect2, varscan2
- ZNF687 | c.2598C>G p.L866= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as rs762887000, COSV55015828; called by muse, mutect2, varscan2
- AMACR | c.739+1325C>T | Intron (SNP) | VAF 57/106 reads (54%) | catalogued as COSV100163096; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500860 G>A | 5'Flank (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- CAST | c.-84C>G | 5'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as COSV57783084; called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1756G>T | RNA (SNP) | VAF 7/10 reads (70%) | catalogued as COSV101181733; called by muse, varscan2
- COMMD9 | chr11:36271672 G>A | 3'Flank (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- FBXW7 | c.501+29049C>G | Intron (SNP) | VAF 34/83 reads (41%) | catalogued as rs1429643705, COSV99657690; called by muse, mutect2, varscan2
- FGFR3 | c.*1427del | 3'UTR (DEL) | VAF 197/333 reads (59%) | catalogued as COSV53399458; called by mutect2, pindel, varscan2
- LDB3 | c.690-4783C>T | Intron (SNP) | VAF 89/348 reads (26%) | catalogued as COSV53938951; called by muse, mutect2, varscan2
- MRM2 | c.298+226G>C | Intron (SNP) | VAF 71/158 reads (45%) | catalogued as COSV54247684; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 27/38 reads (71%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
